Somatic mutation profile of tumor specimen BA2894D (aliquot aq-BA2894D) from BEATAML1.0 case 2109, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,942 days).
Specimen BA2894D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7da0bc11-1ad6-47d7-a528-43a3e5cc2d40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2815D (Solid Tissue Normal), aliquot aq-BA2815D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4cdee71-09ec-4a78-a78a-3f0ebe3a2075

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 2, Intron 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf105 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100877918; called by muse, mutect2, varscan2
- MYH7 | c.4732G>T p.E1578* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV62523003; called by muse, mutect2
- NPR2 | c.967G>A p.V323M | Missense Mutation (SNP) | VAF 120/346 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV61310225; called by muse, varscan2
- WT1 | c.1106C>A p.S369* | Nonsense Mutation (SNP) | VAF 76/232 reads (33%) | catalogued as CM971595, COSV60065297; called by muse, varscan2
- CTCF | c.1087-1G>A p.X363_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2
- KRTAP4-3 | c.513C>G p.C171W | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- LANCL3 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MET | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ABCA8 | c.3174T>C p.L1058= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- SPINK5 | c.2862T>A p.A954= | Silent (SNP) | VAF 97/328 reads (30%) | called by muse, mutect2, varscan2
- TTLL5 | c.3666C>T p.C1222= | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as rs141359185; called by muse, mutect2, varscan2
- ZFHX4 | c.2364C>T p.S788= | Silent (SNP) | VAF 51/119 reads (43%) | catalogued as rs1418043692, COSV99262269; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 10/94 reads (11%) | catalogued as rs201441562; called by pindel, varscan2
- COL13A1 | c.*2G>A | 3'UTR (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
